Surgical pathology report (de-identified scan), TCGA case TCGA-ZP-A9D2, project TCGA-LIHC (Liver Hepatocellular Carcinoma), tissue source site Medical College of Wisconsin, specimen TCGA-ZP-A9D2-01A (Primary Tumor).

[page 1 of 8]
Results History

SURG PATH FINAL REPORT

Entry Information

Entry Date and Time

Lab Status
Edited

Entered by

Component Results

Component

SURG PATH FINAL REPORT

Accession #:

Specimen:

Date of Procedure:

Performing Clinician:

- A. Gallbladder
- B. Tumor in border of segment 7 and 8
- C. Left lateral segment and section segment 4

Clinical Notes:

Liver tumor HCC. C) Fresh tissue saved for tissue bank.

Diagnosis:

REVISED REPORT

*ICD O-3
Carcinoma, hepatocellular NOS
8170/3*

*Site: Liver C22.0
JW 2/3/14*

- A. Gallbladder, cholecystectomy:
- Chronic cholecystitis.
- Negative for dysplasia or malignancy.
- B. Tumor, liver segment 7 and 8, resection:
- Multifocal moderately differentiated hepatocellular carcinoma, completely excised.
- AJCC stage: pT2 pNX pMX.
- See Tumor Characteristics.
- Chronic HCV hepatitis with minimal activity and cirrhosis (grade 1, stage 4).
- Mild siderosis (+1).
- C. Liver, left lateral segment and segment 4 section, resection:
- Solitary moderately differentiated hepatocellular carcinoma with parenchymal margin involvement.
- See specimen B for AJCC staging and Tumor Characteristics sheet.

REVISED REPORT COMMENT: This report is revised to make a change in the AJCC staging in the diagnosis for specimen B from pN0 to pNX (underlined above). None of the other

[page 2 of 8]
[REDACTED]

original text has been altered.

(Electronically signed by)
Verified:

Accession #:

Tumor Characteristics:

B: Liver, Resection (AJCC 7th Ed., 2010)

MACROSCOPIC

SPECIMEN TYPE:

Partial right segmentectomy

FOCALITY:

Multiple (specify location): Segment 7, 8, and 4 (specimen C)

TUMOR SIZE:

Greatest Dimension: 3.3 x 2.5 x 2.5 cm (specimen C). 2.0 x 2.0 x 1.7 (specimen B, first nodule), 0.5 x 0.5 x 0.5 cm (specimen B, second nodule), 0.5 x 0.5 x 0.5 cm (specimen B, third nodule)

MICROSCOPIC

HISTOLOGIC TYPE:

Hepatocellular carcinoma

HISTOLOGIC GRADE:

GII: Moderately differentiated

PRIMARY TUMOR (pT):

pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm

REGIONAL LYMPH NODES (pN):

pNX: Regional lymph nodes cannot be assessed

DISTANT METASTASIS (pM):

Specify site(s), if known: pMX: Cannot be assessed

AJCC STAGING (pTNM):

pT2 pNX pMX

MARGINS:

Bile duct margin cannot be assessed

Other margin - specify margin: Parenchymal margin involved by invasive carcinoma - specimen C (slide C3)

LYMPH-VASCULAR INVASION:

Macroscopic Venous (Large Vessel) Invasion

Not identified

Microscopic (Small Vessel) Invasion

Not identified

ADDITIONAL PATHOLOGIC FINDINGS:

Cirrhosis/fibrosis

[page 3 of 8]
Gross:

A. The specimen is labeled "gallbladder." Received in formalin is a 29 gram, 7.0 x 3.0 x 2.0 cm, gallbladder. The cystic duct margin is removed and the specimen is opened to reveal a pink-tan velvety mucosa with a wall thickness of 0.1 cm. Representative sections are submitted in cassette A.

Accession #:

B. The specimen is labeled "tumor in border of segment 7 and 8." Received in formalin is a 34.6 gram, 4.8 x 4.5 x 3.5 cm, portion of liver. The specimen has been previously incised to reveal three nodules. The first nodule measures 2.0 x 2.0 x 1.7 cm and is 0.3 cm from the closest parenchymal margin and 0.5 cm from the closest capsular margin. The second measures 0.5 x 0.5 x 0.5 cm and abuts the capsule and is 0.5 cm from the closest parenchymal margin. The third measures 0.5 x 0.5 x 0.5 cm and is 0.1 cm from the capsule and 1.6 cm from the closest parenchymal margin. The parenchymal surface is inked black. Representative sections are submitted as follows:

Cassette Designation:

B1-2 Representative section of first, second, and third nodules with closest capsular margin for all three and closest parenchymal margin for nodules 2 and 3.

B3 Representative section of first nodule with closest parenchymal margin

C. The specimen is labeled "left lateral segment and section segment 4." Received in formalin is a 324 gram, 16.0 x 12.5 x 3.5 cm, portion of liver. The specimen has been previously incised to reveal a 3.3 x 2.5 x 2.5 cm firm, tan, nodular lesion which is 0.5 cm from the capsular margin and appears to abut the parenchymal margin. The remaining portion of the liver is grossly unremarkable without identifiable masses or lesions. The parenchymal margin is inked black. No large identifiable vessels are noted. Representative sections are submitted as follows:

Cassette Designation:

C1 Portion of liver nodule with closest capsular margin

C2-3 Portion of liver lesion abutting black inked parenchymal surface

C4 Additional representative section of liver lesion

C5 Representative section of grossly

[page 4 of 8]
[REDACTED]

unremarkable liver

Accession #:

Microscopic:

Histological examinations have been performed on specimens A-C.

B and C. The specimens are histologically similar and are described together. Sections show portions of liver parenchyma that demonstrate mixed macro- and micronodular cirrhosis highlighted by a trichrome stain performed on specimen C. Multiple large nodules of moderately differentiated hepatocellular carcinoma are present that exhibit an architecture with small cell change and pseudocanalicular structures with prominent admixed vasculature. The tumor cells contain bubbly lipid-laden cytoplasm and pleomorphic nuclei with vesicular chromatin and very prominent nucleolus as well as a high nuclear cytoplasmic ratio. The tumor cells are present as nests and pseudoglandular structures and exhibit occasional mitotic figures and apoptoses. The tumor cell infiltrate involves the cauterized and black inked parenchymal margin for specimen C. However, the remaining nodules in the specimen are well-circumscribed by dense fibrous capsule. A reticulin stain performed on specimen B and C highlight reticulin fiber loss within the tumor cell nodules and thickening of cell plates as well as highlighting the regenerative nodules in the uninvolved liver. The background liver exhibits mixed macro- and micronodular lymphoplasmacytic infiltrate with focal areas of bile duct proliferation. A Prussian Blue stain for iron demonstrates mild siderosis (+1) in the form of intrahepatic and kupffer cell iron. Controls stained appropriately.

Administrative Notes:

CPT:

[REDACTED]

[page 5 of 8]
[REDACTED]

No charge codes are associated with this case.

Entry Information

Entry Date and Time

Lab Status
Final result

Entered by

Component Results

Component

SURG PATH FINAL REPORT

Accession #:

Specimen:

Date of Procedure:

Performing Clinician:

- A. Gallbladder
- B. Tumor in border of segment 7 and 8
- C. Left lateral segment and section segment 4

Clinical Notes:

Liver tumor HCC. C) Fresh tissue saved for tissue bank.

Diagnosis:

- A. Gallbladder, cholecystectomy:
- Chronic cholecystitis.
- Negative for dysplasia or malignancy.
- B. Tumor, liver segment 7 and 8, resection:
- Multifocal moderately differentiated hepatocellular carcinoma, completely excised.
- AJCC stage: pT2 pN0 pMX.
- See Tumor Characteristics.
- Chronic HCV hepatitis with minimal activity and cirrhosis (grade 1, stage 4).
- Mild siderosis (+1).
- C. Liver, left lateral segment and segment 4 section, resection:
- Solitary moderately differentiated hepatocellular carcinoma with parenchymal margin involvement.
- See specimen B for AJCC staging and Tumor Characteristics sheet.

(Electronically signed by)

Verified:

[page 6 of 8]
Tumor Characteristics:
B: Liver, Resection (AJCC 7th Ed., 2010)
MACROSCOPIC
SPECIMEN TYPE:
Partial right segmentectomy
FOCALITY:

Accession #:

Multiple (specify location): Segment 7, 8, and 4 (specimen C)

TUMOR SIZE:

Greatest Dimension: 3.3 x 2.5 x 2.5 cm (specimen C). 2.0 x 2.0 x 1.7 (specimen B, first nodule), 0.5 x 0.5 x 0.5 cm (specimen B, second nodule), 0.5 x 0.5 x 0.5 cm (specimen B, third nodule)

MICROSCOPIC

HISTOLOGIC TYPE:

Hepatocellular carcinoma

HISTOLOGIC GRADE:

GII: Moderately differentiated

PRIMARY TUMOR (pT):

pT2: Solitary tumor with vascular invasion or multiple tumors none more than 5 cm

REGIONAL LYMPH NODES (pN):

pNX: Regional lymph nodes cannot be assessed

DISTANT METASTASIS (pM):

Specify site(s), if known: pMX: Cannot be assessed

AJCC STAGING (pTNM):

pT2 pNX pMX

MARGINS:

Bile duct margin cannot be assessed

Other margin - specify margin: Parenchymal margin involved by invasive carcinoma - specimen C (slide C3)

LYMPH-VASCULAR INVASION:

Macroscopic Venous (Large Vessel) Invasion

Not identified

Microscopic (Small Vessel) Invasion

Not identified

ADDITIONAL PATHOLOGIC FINDINGS:

Cirrhosis/fibrosis

Gross:

A. The specimen is labeled "gallbladder." Received in formalin is a 29 gram, 7.0 x 3.0 x 2.0 cm, gallbladder. The cystic duct margin is removed and the specimen is opened to reveal a pink-tan velvety mucosa with a wall thickness of 0.1 cm. Representative sections are submitted in cassette A.

[page 7 of 8]
[REDACTED]

B. The specimen is labeled "tumor in border of segment 7 and 8." Received in formalin is a 34.6 gram, 4.8 x 4.5 x 3.5 cm, portion of liver. The specimen has been previously incised to reveal three nodules. The first nodule measures 2.0 x 2.0 x 1.7 cm and is 0.3 cm from the closest parenchymal margin and 0.5 cm from the closest capsular margin. The second measures 0.5 x 0.5 x 0.5 cm and abuts

Accession #:

the capsule and is 0.5 cm from the closest parenchymal margin. The third measures 0.5 x 0.5 x 0.5 cm and is 0.1 cm from the capsule and 1.6 cm from the closest parenchymal margin. The parenchymal surface is inked black. Representative sections are submitted as follows:

Cassette Designation:

B1-2 Representative section of first, second, and third nodules with closest capsular margin for all three and closest parenchymal margin for nodules 2 and 3.
B3 Representative section of first nodule with closest parenchymal margin

C. The specimen is labeled "left lateral segment and section segment 4." Received in formalin is a 324 gram, 16.0 x 12.5 x 3.5 cm, portion of liver. The specimen has been previously incised to reveal a 3.3 x 2.5 x 2.5 cm firm, tan, nodular lesion which is 0.5 cm from the capsular margin and appears to abut the parenchymal margin. The remaining portion of the liver is grossly unremarkable without identifiable masses or lesions. The parenchymal margin is inked black. No large identifiable vessels are noted. Representative sections are submitted as follows:

Cassette Designation:

C1 Portion of liver nodule with closest capsular margin
C2-3 Portion of liver lesion abutting black inked parenchymal surface
C4 Additional representative section of liver lesion
C5 Representative section of grossly unremarkable liver

[page 8 of 8]
Microscopic:

Histological examinations have been performed on specimens A-C.

B and C. The specimens are histologically similar and are described together. Sections show portions of liver parenchyma that demonstrate mixed macro- and micronodular cirrhosis highlighted by a trichrome stain performed on specimen C. Multiple large nodules of moderately

Accession #:

differentiated hepatocellular carcinoma are present that exhibit an architecture with small cell change and pseudocanalicular structures with prominent admixed vasculature. The tumor cells contain bubbly lipid-laden cytoplasm and pleomorphic nuclei with vesicular chromatin and very prominent nucleolus as well as a high nuclear cytoplasmic ratio. The tumor cells are present as nests and pseudoglandular structures and exhibit occasional mitotic figures and apoptoses. The tumor cell infiltrate involves the cauterized and black inked parenchymal margin for specimen C. However, the remaining nodules in the specimen are well-circumscribed by dense fibrous capsule. A reticulin stain performed on specimen B and C highlight reticulin fiber loss within the tumor cell nodules and thickening of cell plates as well as highlighting the regenerative nodules in the uninvolved liver. The background liver exhibits mixed macro- and micronodular cirrhosis with portal areas that exhibit dense lymphoplasmacytic infiltrate with focal areas of bile duct proliferation. A Prussian Blue stain for iron demonstrates mild siderosis (+1) in the form of intrahepatic and kupffer cell iron. Controls stained appropriately.

Administrative Notes:

CPT:

No charge codes are associated with this case.

Entry Information

Entry Date and Time

Lab Status
In process

Entered by

Source: NCI Genomic Data Commons file d16fd7f6-1094-4722-9beb-ebfef86c827f (TCGA-ZP-A9D2.260D67D7-9E8C-4A3B-B031-8AB4A05BC688.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).